Somatic mutation profile of tumor specimen TCGA-CA-6717-01A (aliquot TCGA-CA-6717-01A-11D-1835-10) from TCGA case TCGA-CA-6717, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 57.5 years (20,984 days).
Specimen TCGA-CA-6717-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76034bd4-7a45-4c2a-9bea-7e7a4b1ceaae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CA-6717-10A (Blood Derived Normal), aliquot TCGA-CA-6717-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35fa9eee-3082-4cf7-8b15-1dafafafe31e

The open-access MAF lists 9,830 somatic variants for this specimen: 7,339 protein-altering or splice-affecting, 1,593 silent, 898 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6,340, Silent 1,593, Nonsense Mutation 779, 3'UTR 448, Intron 244, Splice Site 106, RNA 75, Splice Region 68, 5'UTR 67, 3'Flank 35, 5'Flank 28, Frame Shift Ins 22.

Variants (750 of 9,830; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAT1 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs370720208, CM075969; ClinVar: uncertain significance / likely pathogenic; called by mutect2, varscan2
- ALOX12B | c.1642C>T p.R548W | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs397514532, CM081154, COSV59874078; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- APC | c.4175C>A p.S1392* | Nonsense Mutation (SNP) | VAF 16/86 reads (19%) | catalogued as rs786204170, CM960068, CM990162, COSV57326586; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 21/125 reads (17%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATM | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 14/59 reads (24%) | hotspot (GDC flag); catalogued as rs772821016, CM030188, CS991299, COSV53725394; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BEST1 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs281865239, CM003486, COSV57120998; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRCA2 | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 11/66 reads (17%) | catalogued as rs397507646, CM062477, COSV66461936; ClinVar: pathogenic; called by mutect2, varscan2
- CEP57 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 34/144 reads (24%) | catalogued as rs387906977, CM113693, COSV57689518; ClinVar: pathogenic; called by muse, varscan2
- COL7A1 | c.1732C>T p.R578* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as rs144023803, CM940314; ClinVar: pathogenic; called by mutect2, varscan2
- EYA1 | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 38/172 reads (22%) | catalogued as rs1131691667, CM001984, COSV58158250; ClinVar: pathogenic; called by muse, varscan2
- EYS | c.4120C>T p.R1374* | Nonsense Mutation (SNP) | VAF 26/133 reads (20%) | catalogued as rs928803207, CM107715, COSV58199378; ClinVar: pathogenic; called by muse, varscan2
- FAT1 | c.4880G>A p.R1627Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | hotspot (GDC flag); SIFT tolerated (0.34); PolyPhen benign (0.043); catalogued as rs767331775, COSV71672487; called by mutect2, varscan2
- FBXW7 | c.1972C>T p.R658* (on ENST00000281708 / NM_001349798.2; = p.R578* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 17/123 reads (14%) | hotspot (GDC flag); catalogued as COSV55892162, COSV55908751; called by muse, mutect2, varscan2
- FBXW7 | c.1178G>A p.R393Q (on ENST00000281708 / NM_001349798.2; = p.R313Q on NM_018315.5) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs1390822119, COSV55892508, COSV55937382; called by muse, mutect2
- FBXW7 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 32/123 reads (26%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs200698994; called by muse, mutect2, varscan2
- KCNE2 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.991); catalogued as rs199473367, CM003450, COSV51710393; ClinVar: likely pathogenic / not provided; called by muse, varscan2
- MYLK | c.4459C>T p.R1487* | Nonsense Mutation (SNP) | VAF 12/164 reads (7%) | catalogued as rs886229659, CM158147; ClinVar: pathogenic; called by muse, mutect2
- NAP1L3 | c.1506G>T p.K502N | Missense Mutation (SNP) | VAF 20/76 reads (26%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV59077525; called by muse, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 16/74 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 44/245 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.51); PolyPhen benign (0.366); catalogued as COSV55875690, COSV55899999; called by muse, mutect2, varscan2
- RAF1 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 16/85 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs80338796, CM073301, COSV52574378, COSV52579821; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- RTKN2 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 20/134 reads (15%) | hotspot (GDC flag); catalogued as rs772033296, COSV65679700, COSV65679972; called by muse, mutect2, varscan2
- SCN2A | c.3631G>A p.E1211K | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs387906684, CM095805, COSV99330257; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 7/60 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TARBP2 | c.571G>T p.E191* (on ENST00000266987 / NM_134323.2; = p.E170* on NM_004178.4) | Nonsense Mutation (SNP) | VAF 15/68 reads (22%) | hotspot (GDC flag); catalogued as COSV57199177; called by muse, mutect2, varscan2
- TGFBR1 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 19/87 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs111854391, CM061221, COSV66624834; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TMCO1 | c.616C>T p.R206* (on ENST00000612311 / NM_001256164.1; = p.R155* on NM_019026.6) | Nonsense Mutation (SNP) | VAF 33/171 reads (19%) | catalogued as rs765379963, COSV100903179, COSV63319044; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TRPM1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/69 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs770561064, COSV56641594; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TRPS1 | c.2854C>T p.R952C (on ENST00000220888 / NM_001330599.2; = p.R965C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs28939069, CM040268, COSV55228014; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.81605T>G p.L27202* (on ENST00000591111; = p.L19778* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 42/139 reads (30%) | catalogued as rs752378132, COSV60319598; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1BG | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs770480372, COSV54053359; called by mutect2, varscan2
- A1CF | c.1546G>A p.E516K (on ENST00000373993 / NM_138932.2; = p.E508K on NM_014576.4) | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs765124661, COSV50959265; called by mutect2, varscan2
- A2M | c.4202G>T p.R1401I | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.202); catalogued as COSV59392097; called by muse, mutect2, varscan2
- A2M | c.2396C>T p.P799L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59392104, COSV59393832; called by muse, mutect2, varscan2
- A2ML1 | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 22/93 reads (24%) | catalogued as COSV55297981; called by muse, mutect2, varscan2
- A2ML1 | c.904G>T p.D302Y | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV55298002; called by muse, mutect2, varscan2
- A2ML1 | c.3656C>A p.T1219N | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV55298017; called by muse, mutect2, varscan2
- A2ML1 | c.3979T>G p.F1327V | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100229408; called by mutect2, varscan2
- AADAC | c.654T>G p.I218M | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as COSV51761224; called by muse, varscan2
- AADACL3 | c.1184G>T p.R395I | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs780900877, COSV60200400; called by muse, mutect2, varscan2
- AAK1 | c.761A>C p.K254T | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68646495; called by muse, varscan2
- AAK1 | c.751T>G p.L251V | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68646501; called by muse, varscan2
- AARS1 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV55747820; called by muse, mutect2, varscan2
- AASDH | c.2443G>T p.E815* | Nonsense Mutation (SNP) | VAF 14/108 reads (13%) | catalogued as COSV99221805; called by muse, mutect2, varscan2
- AASDH | c.1010A>C p.K337T | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as COSV52710325; called by muse, mutect2
- ABCA10 | c.4300G>A p.D1434N | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.134); catalogued as COSV52217810; called by muse, mutect2, varscan2
- ABCA10 | c.4231G>A p.A1411T | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52229261; called by muse, mutect2, varscan2
- ABCA10 | c.3668G>T p.R1223I | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52229274; called by muse, varscan2
- ABCA10 | c.2371G>T p.E791* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as COSV52229282; called by muse, mutect2, varscan2
- ABCA12 | c.7290G>T p.K2430N (on ENST00000272895 / NM_173076.3; = p.K2112N on NM_015657.3) | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs201795274, COSV55974101; called by mutect2, varscan2
- ABCA12 | c.6032A>G p.E2011G (on ENST00000272895 / NM_173076.3; = p.E1693G on NM_015657.3) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55974118; called by muse, mutect2, varscan2
- ABCA12 | c.5089G>A p.D1697N (on ENST00000272895 / NM_173076.3; = p.D1379N on NM_015657.3) | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.602); catalogued as rs1265616723, COSV55953217; called by muse, mutect2
- ABCA12 | c.2920A>C p.N974H (on ENST00000272895 / NM_173076.3; = p.N656H on NM_015657.3) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV55974133; called by muse, mutect2, varscan2
- ABCA12 | c.2684-1G>T p.X895_splice (on ENST00000272895 / NM_173076.3; = p.X577_splice on NM_015657.3) | Splice Site (SNP) | VAF 12/51 reads (24%) | catalogued as rs1349342875, COSV55974149; called by muse, mutect2, varscan2
- ABCA12 | c.1211G>A p.R404Q (on ENST00000272895 / NM_173076.3; = p.R86Q on NM_015657.3) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs752328328, COSV55961290, COSV99789386; called by mutect2, varscan2
- ABCA12 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs762065937, CM130513, COSV55948982; called by muse, mutect2, varscan2
- ABCA13 | c.1886A>G p.K629R | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.779); catalogued as COSV70043011; called by muse, mutect2, varscan2
- ABCA13 | c.2828A>C p.K943T | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.067); catalogued as COSV70043076; called by muse, mutect2
- ABCA13 | c.3220G>A p.D1074N | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.828); catalogued as COSV70043158; called by muse, mutect2, varscan2
- ABCA13 | c.5570G>A p.S1857N | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs1459033707, COSV70043193; called by muse, mutect2, varscan2
- ABCA13 | c.5946G>T p.K1982N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.795); catalogued as COSV70043195; called by muse, mutect2, varscan2
- ABCA13 | c.6793G>T p.E2265* | Nonsense Mutation (SNP) | VAF 30/132 reads (23%) | catalogued as COSV101330198; called by muse, mutect2, varscan2
- ABCA13 | c.9206A>C p.K3069T | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV101447188; called by muse, varscan2
- ABCA13 | c.14108A>C p.K4703T | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.049); catalogued as rs1338500522, COSV68950480; called by muse, mutect2, varscan2
- ABCA6 | c.4774G>T p.E1592* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | catalogued as COSV52644007, COSV52644344, COSV52644677; called by mutect2, varscan2
- ABCA6 | c.3986C>A p.S1329Y | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52644352; called by muse, mutect2, varscan2
- ABCA6 | c.2986C>T p.R996* | Nonsense Mutation (SNP) | VAF 25/100 reads (25%) | catalogued as rs143975041; called by muse, varscan2
- ABCA7 | c.5261G>T p.R1754L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV54027729, COSV54035314, COSV54037489; called by mutect2, varscan2
- ABCA8 | c.1967C>T p.A656V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as rs145869753; called by mutect2, varscan2
- ABCA8 | c.808G>T p.G270C | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1397030729; called by muse, mutect2
- ABCA9 | c.1306T>C p.F436L | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV100383449; called by muse, mutect2, varscan2
- ABCA9 | c.99A>C p.E33D | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60630660; called by muse, mutect2, varscan2
- ABCB1 | c.3628A>C p.S1210R | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55962527; called by muse, mutect2, varscan2
- ABCB1 | c.857G>T p.R286I | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.762); catalogued as COSV55944621, COSV55950626; called by muse, mutect2, varscan2
- ABCB4 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV55932472; called by muse, mutect2, varscan2
- ABCB5 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 23/92 reads (25%) | catalogued as COSV51714014; called by muse, mutect2, varscan2
- ABCB5 | c.2059C>T p.P687S (on ENST00000404938 / NM_001163941.2; = p.P242S on NM_178559.6) | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1207696838; called by muse, mutect2, varscan2
- ABCC1 | c.3677G>A p.S1226N | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.999); catalogued as rs1469910945, COSV60693492; called by muse, mutect2, varscan2
- ABCC10 | c.3184T>C p.S1062P (on ENST00000372530 / NM_001198934.2; = p.S1034P on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as rs1354126924, COSV55093632; called by muse, mutect2, varscan2
- ABCC12 | c.2304G>T p.Q768H | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as COSV60917967; called by muse, mutect2, varscan2
- ABCC12 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.867); catalogued as rs751380328, COSV60917978; called by mutect2, varscan2
- ABCC12 | c.71G>T p.R24I | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV60917986; called by muse, mutect2, varscan2
- ABCC3 | c.1066A>G p.M356V | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99559756; called by muse, mutect2, varscan2
- ABCC5 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV55595887; called by muse, varscan2
- ABCC8 | c.4142G>A p.G1381D | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769926016; called by mutect2, varscan2
- ABCC8 | c.3539A>G p.Y1180C | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV56857033; called by muse, mutect2, varscan2
- ABCD2 | c.1949C>T p.A650V | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.186); catalogued as COSV58054860; called by muse, mutect2, varscan2
- ABCD2 | c.893G>T p.R298I | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58054867; called by muse, mutect2, varscan2
- ABCG2 | c.1604C>A p.S535Y | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as COSV52949164; called by muse, mutect2, varscan2
- ABCG8 | c.1832G>A p.R611K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as rs749407558, COSV55393098, COSV55396475; called by mutect2, varscan2
- ABHD16A | c.1618G>T p.E540* | Nonsense Mutation (SNP) | VAF 8/86 reads (9%) | catalogued as COSV65452510; called by muse, mutect2, varscan2
- ABHD17B | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1263740394, COSV61009064; called by muse, mutect2, varscan2
- ABHD18 | c.1150C>T p.R384* (on ENST00000398965 / NM_001039717.2; = p.R291* on NM_025097.2 and 10 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 30/111 reads (27%) | catalogued as rs1355205312, COSV66293606; called by muse, mutect2, varscan2
- ABI1 | c.1335G>T p.K445N | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV61015312; called by muse, mutect2, varscan2
- ABI3BP | c.485A>C p.E162A | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52549978; called by muse, mutect2, varscan2
- ABI3BP | c.332A>C p.K111T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52528342; called by muse, mutect2
- ABL2 | c.3487A>G p.N1163D (on ENST00000502732 / NM_007314.4; = p.N1148D on NM_005158.5) | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.324); catalogued as COSV61020292; called by muse, mutect2, varscan2
- ABR | c.1437T>A p.C479* (on ENST00000302538 / NM_021962.5; = p.C442* on NM_001092.5) | Nonsense Mutation (SNP) | VAF 8/73 reads (11%) | catalogued as COSV99348528; called by muse, mutect2, varscan2
- ABT1 | c.524T>C p.V175A | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV51292766; called by muse, mutect2, varscan2
- AC006059.2 | c.855G>T p.W285C | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100045207, COSV59609276, COSV59610169; called by muse, mutect2, varscan2
- AC006059.2 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747323363, COSV59609283; called by muse, mutect2, varscan2
- AC008397.2 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs374321161; called by muse, mutect2, varscan2
- AC008676.3 | c.119T>C p.F40S | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56638041; called by muse, mutect2, varscan2
- AC009779.3 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 13/65 reads (20%) | catalogued as COSV57726202; called by muse, mutect2, varscan2
- AC013477.1 | c.2149T>C p.F717L | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.173); catalogued as COSV53655143; called by muse, mutect2, varscan2
- AC013489.1 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as COSV51553414; called by muse, mutect2, varscan2
- AC098582.1 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs548433496, COSV52024164; called by muse, mutect2, varscan2
- AC098582.1 | c.2245G>T p.E749* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as COSV52021352; called by muse, mutect2, varscan2
- AC100868.1 | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV51838911; called by muse, mutect2, varscan2
- AC100868.1 | c.1439C>A p.S480Y | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs766366784, COSV51839810, COSV99225154; called by mutect2, varscan2
- AC126283.2 | c.976T>G p.S326A | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.173); catalogued as COSV67099832; called by muse, varscan2
- AC126283.2 | c.49T>G p.F17V | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs779272662, COSV67099838; called by mutect2, varscan2
- ACACA | c.3349C>T p.R1117* | Nonsense Mutation (SNP) | VAF 39/184 reads (21%) | catalogued as rs1439805556; called by muse, mutect2, varscan2
- ACACB | c.266G>T p.R89I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs774959869, COSV58129464, COSV58130111; called by muse, mutect2, varscan2
- ACACB | c.6103G>T p.E2035* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as COSV58145311; called by muse, mutect2, varscan2
- ACAD11 | c.1212C>A p.F404L | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.586); catalogued as COSV53901135; called by muse, mutect2, varscan2
- ACADM | c.217-7C>A | Splice Region (SNP) | VAF 17/86 reads (20%) | catalogued as COSV63721032; called by muse, mutect2, varscan2
- ACAN | c.1083C>A p.F361L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.26); catalogued as COSV61364931; called by muse, mutect2, varscan2
- ACAP2 | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 56/306 reads (18%) | catalogued as COSV58755480; called by muse, mutect2, varscan2
- ACAP2 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1251813082, COSV58755489; called by muse, varscan2
- ACAP2 | c.437G>T p.R146I | Missense Mutation (SNP) | VAF 62/299 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV58755497; called by muse, varscan2
- ACE2 | c.1540C>T p.R514* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as rs1352194082, COSV53024322; called by muse, mutect2, varscan2
- ACLY | c.1364C>A p.S455Y | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61252856; called by muse, mutect2, varscan2
- ACOD1 | c.928G>A p.V310M | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.483); catalogued as COSV66291916; called by muse, varscan2
- ACOT2 | c.133C>A p.L45M | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.094); catalogued as COSV53151515; called by muse, mutect2, varscan2
- ACOT4 | c.785A>C p.N262T | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.044); catalogued as COSV58336307; called by muse, mutect2, varscan2
- ACOXL | c.911C>A p.A304D | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV67738245; called by muse, mutect2, varscan2
- ACRBP | c.893T>C p.M298T | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV57522933; called by muse, mutect2, varscan2
- ACSBG1 | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs751633265; called by mutect2, varscan2
- ACSBG2 | c.1175A>C p.H392P | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.53); catalogued as COSV53127587; called by muse, mutect2, varscan2
- ACSL4 | c.1777A>G p.K593E (on ENST00000340800 / NM_022977.2; = p.K552E on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100539033; called by muse, mutect2, varscan2
- ACSM1 | c.774G>T p.K258N | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.934); catalogued as COSV54639755; called by muse, mutect2, varscan2
- ACSM1 | c.104T>G p.F35C | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV54639765; called by muse, mutect2, varscan2
- ACSM2A | c.382C>T p.R128* (on ENST00000219054; = p.R49* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 37/222 reads (17%) | catalogued as rs748565082, COSV54589440; called by muse, mutect2, varscan2
- ACSM2A | c.823G>T p.E275* (on ENST00000219054; = p.E196* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 23/113 reads (20%) | catalogued as COSV54587099, COSV54589449; called by muse, mutect2, varscan2
- ACSM4 | c.248A>C p.K83T | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV68069237; called by muse, mutect2, varscan2
- ACSM4 | c.982G>A p.V328M | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs752916520, COSV68067373, COSV68069242; called by muse, mutect2, varscan2
- ACSM4 | c.1672G>T p.E558* | Nonsense Mutation (SNP) | VAF 17/71 reads (24%) | catalogued as COSV68069249; called by muse, mutect2, varscan2
- ACSM6 | c.63C>A p.C21* | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | catalogued as COSV58980646; called by muse, mutect2, varscan2
- ACSS2 | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53628144; called by muse, mutect2, varscan2
- ACTA1 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); catalogued as CM095322, COSV64204117; called by muse, mutect2, varscan2
- ACTA2 | c.386T>C p.F129S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV56518060; called by muse, mutect2
- ACTB | c.254T>C p.I85T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV100079929; called by mutect2, varscan2
- ACTC1 | c.189G>T p.K63N | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.925); catalogued as COSV51761274; called by muse, mutect2, varscan2
- ACTN1 | c.1504A>C p.K502Q | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV51997078; called by muse, varscan2
- ACTR3 | c.657A>C p.Q219H | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV54303855; called by muse, mutect2, varscan2
- ACVR1B | c.1230T>G p.Y410* | Nonsense Mutation (SNP) | VAF 53/256 reads (21%) | catalogued as COSV57780018; called by muse, mutect2, varscan2
- ACVR1B | c.1330C>T p.R444* | Nonsense Mutation (SNP) | VAF 13/65 reads (20%) | catalogued as COSV57774850; called by muse, mutect2, varscan2
- ADA2 | c.620T>G p.F207C | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1292778015, COSV52833725; called by muse, varscan2
- ADAD1 | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56645316, COSV56647088; called by muse, mutect2, varscan2
- ADAM15 | c.111G>T p.E37D | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55062992; called by muse, mutect2, varscan2
- ADAM15 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV55129662; called by muse, mutect2, varscan2
- ADAM17 | c.956A>G p.E319G | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV60401724; called by muse, mutect2, varscan2
- ADAM18 | c.989A>G p.D330G | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs777580479; called by muse, mutect2, varscan2
- ADAM18 | c.1568C>A p.S523Y | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (1); PolyPhen possibly damaging (0.642); catalogued as rs781004298, COSV55843581; called by muse, mutect2, varscan2
- ADAM2 | c.1814G>T p.R605I | Missense Mutation (SNP) | VAF 19/222 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV99696648; called by muse, mutect2
- ADAM2 | c.1758G>T p.K586N | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV99697794; called by muse, mutect2, varscan2
- ADAM23 | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.317); catalogued as rs775680717, COSV52227947, COSV52228939; called by muse, mutect2, varscan2
- ADAM33 | c.2370G>T p.E790D | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.173); catalogued as COSV62936796; called by muse, mutect2, varscan2
- ADAM7 | c.1634G>T p.R545I | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV51537821, COSV51546204; called by muse, mutect2, varscan2
- ADAMTS12 | c.2012G>A p.G671D | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61277989; called by muse, mutect2
- ADAMTS12 | c.783C>G p.Y261* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100711634; called by mutect2, varscan2
- ADAMTS12 | c.390G>T p.K130N | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as COSV61266212, COSV61267255; called by muse, mutect2, varscan2
- ADAMTS16 | c.2866C>T p.R956W | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs750241793, COSV56993309, COSV57005904; called by mutect2, varscan2
- ADAMTS17 | c.2377G>A p.E793K | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.709); catalogued as rs139385294; called by muse, mutect2, varscan2
- ADAMTS18 | c.2000T>G p.F667C | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV51422647; called by muse, mutect2, varscan2
- ADAMTS18 | c.774G>T p.K258N | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV51420697; called by mutect2, varscan2
- ADAMTS18 | c.548A>C p.Q183P | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV51398391, COSV51422655; called by muse, mutect2, varscan2
- ADAMTS20 | c.5423A>G p.D1808G | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV67138525; called by muse, mutect2, varscan2
- ADAMTS20 | c.1856A>G p.E619G | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV101240293; called by mutect2, varscan2
- ADAMTS9 | c.1822A>G p.I608V | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as rs763814933; called by mutect2, varscan2
- ADAMTS9 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.034); catalogued as COSV55789800; called by muse, mutect2
- ADAMTSL3 | c.4288C>T p.P1430S | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as COSV54467675; called by muse, mutect2, varscan2
- ADAR | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.053); catalogued as COSV52720617; called by muse, varscan2
- ADAR | c.269T>G p.I90S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.026); catalogued as COSV52720635; called by muse, varscan2
- ADARB1 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.86); PolyPhen benign (0.146); catalogued as COSV62347878; called by muse, mutect2, varscan2
- ADAT1 | c.1438T>C p.W480R | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57188345; called by muse, varscan2
- ADCY1 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52041902; called by muse, mutect2, varscan2
- ADCY1 | c.3277C>T p.P1093S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs865925348; called by muse, mutect2, varscan2
- ADCY4 | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV60257419; called by muse, mutect2, varscan2
- ADCY8 | c.1972T>G p.L658V | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.675); catalogued as COSV53925801; called by muse, varscan2
- ADCY9 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs772697228, COSV53574136; called by mutect2, varscan2
- ADD1 | c.426G>T p.E142D | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53273942; called by muse, mutect2
- ADGB | c.927A>C p.K309N | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV58863962; called by muse, varscan2
- ADGB | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.755); catalogued as COSV58863975; called by muse, varscan2
- ADGB | c.1583T>G p.F528C | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV100484619; called by muse, varscan2
- ADGB | c.3938C>A p.S1313Y | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV58850862; called by muse, mutect2, varscan2
- ADGRA1 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1465038037, COSV66927281; called by muse, mutect2, varscan2
- ADGRA3 | c.3952G>A p.E1318K | Missense Mutation (SNP) | VAF 48/246 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs576557418, COSV51567903; called by muse, mutect2, varscan2
- ADGRB3 | c.511T>G p.L171V | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV65418187; called by muse, mutect2, varscan2
- ADGRB3 | c.1828A>C p.N610H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV65418195; called by muse, varscan2
- ADGRB3 | c.2284C>A p.L762I | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as rs142662373, COSV65414198; called by mutect2, varscan2
- ADGRB3 | c.3293C>A p.S1098Y | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53259030; called by muse, mutect2, varscan2
- ADGRE1 | c.1377G>T p.K459N | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.115); catalogued as COSV51680623; called by muse, mutect2, varscan2
- ADGRF1 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143178573, COSV51947538; called by mutect2, varscan2
- ADGRF2 | c.759G>A p.W253* (on ENST00000296862 / NM_001368115.2; = p.W185* on NM_153839.7) | Nonsense Mutation (SNP) | VAF 19/88 reads (22%) | catalogued as COSV57291739; called by muse, mutect2, varscan2
- ADGRF3 | c.2464G>A p.A822T (on ENST00000311519 / NM_001145168.1; = p.A623T on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201233414; called by mutect2, varscan2
- ADGRF4 | c.503A>C p.K168T | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as COSV51957114; called by muse, mutect2, varscan2
- ADGRF5 | c.2733G>T p.Q911H | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.417); catalogued as COSV51939616; called by muse, mutect2, varscan2
- ADGRG2 | c.2363T>G p.I788S (on ENST00000379869 / NM_001079858.3; = p.I785S on NM_005756.4) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV61341181; called by muse, mutect2, varscan2
- ADGRG2 | c.395A>C p.K132T (on ENST00000379869 / NM_001079858.3; = p.K129T on NM_005756.4) | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as COSV61341185; called by muse, mutect2, varscan2
- ADGRG4 | c.1961C>A p.T654N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.981); catalogued as COSV54966038; called by muse, mutect2, varscan2
- ADGRG4 | c.3848C>T p.S1283F | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.086); catalogued as COSV54957590, COSV54966049; called by muse, mutect2, varscan2
- ADGRG4 | c.5974C>A p.L1992I | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.033); catalogued as COSV54950689; called by muse, mutect2, varscan2
- ADGRG4 | c.7034T>C p.L2345S | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54966076; called by muse, mutect2
- ADGRG7 | c.856G>T p.V286F | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV56300937; called by muse, varscan2
- ADGRG7 | c.1895T>C p.V632A | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as COSV56300948; called by muse, varscan2
- ADGRL2 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1041419067, COSV54651627; called by muse, mutect2, varscan2
- ADGRL2 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746200328, COSV54660115; called by mutect2, varscan2
- ADGRL2 | c.2495C>T p.A832V (on ENST00000370717 / NM_001366005.1; = p.A819V on NM_012302.4) | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as COSV54687508; called by muse, mutect2, varscan2
- ADGRL2 | c.3385T>C p.S1129P (on ENST00000370717 / NM_001366005.1; = p.S1116P on NM_012302.4) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV54687551; called by muse, mutect2, varscan2
- ADGRL3 | c.1176A>C p.K392N (on ENST00000506720 / NM_001322402.2; = p.K324N on NM_015236.6) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV72273149; called by muse, varscan2
- ADGRL3 | c.3429G>A p.W1143* (on ENST00000506720 / NM_001322402.2; = p.W1075* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 10/99 reads (10%) | catalogued as COSV101547379; called by muse, varscan2
- ADGRL4 | c.62A>C p.N21T | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.01); catalogued as COSV66065555; called by muse, varscan2
- ADGRV1 | c.7612T>G p.F2538V | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67979484; called by muse, mutect2, varscan2
- ADGRV1 | c.9199C>A p.L3067I | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV101316453; called by muse, mutect2
- ADGRV1 | c.11288C>A p.S3763Y | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV67996184; called by mutect2, varscan2
- ADGRV1 | c.12911C>T p.T4304M | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs145209242, COSV67989514; called by muse, varscan2
- ADGRV1 | c.12971T>G p.F4324C | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67994545; called by muse, varscan2
- ADH1C | c.736G>T p.D246Y | Missense Mutation (SNP) | VAF 32/354 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72463609; called by muse, mutect2
- ADH5 | c.1105C>T p.R369* | Nonsense Mutation (SNP) | VAF 12/98 reads (12%) | catalogued as rs761349329, COSV56447491; called by mutect2, varscan2
- ADHFE1 | c.569C>A p.T190N | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1166388537, COSV52558901; called by muse, varscan2
- ADRB2 | c.324T>G p.F108L | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.02); catalogued as COSV60006212; called by muse, mutect2, varscan2
- ADRB3 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1353983568, COSV61462615; called by muse, mutect2, varscan2
- ADSS1 | c.1369T>C p.F457L | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.54); catalogued as COSV58276162; called by muse, mutect2, varscan2
- AFAP1L2 | c.159G>C p.E53D | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV58418385; called by muse, mutect2, varscan2
- AFDN | c.131G>T p.R44I | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60043522; called by muse, varscan2
- AFDN | c.231G>T p.E77D | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV60055950; called by muse, varscan2
- AFDN | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 23/166 reads (14%) | catalogued as COSV60055976; called by muse, mutect2, varscan2
- AFDN | c.1013T>G p.I338S | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV60056006; called by muse, mutect2, varscan2
- AFF1 | c.3514T>G p.F1172V | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV57123684; called by muse, mutect2, varscan2
- AFF3 | c.2693C>A p.S898Y | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.94); catalogued as COSV57849450, COSV57864936; called by muse, varscan2
- AFF3 | c.2597C>T p.A866V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV57871873; called by muse, varscan2
- AFF3 | c.556G>T p.V186L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as COSV57871881; called by muse, mutect2, varscan2
- AFF3 | c.357G>T p.Q119H | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.694); catalogued as COSV100418932; called by muse, mutect2, varscan2
- AFF4 | c.2983G>T p.D995Y | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54799458; called by muse, mutect2, varscan2
- AFF4 | c.1133C>T p.S378F | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs1259299926, COSV54791367; called by muse, mutect2, varscan2
- AFG3L2 | c.2272G>T p.E758* | Nonsense Mutation (SNP) | VAF 23/104 reads (22%) | catalogued as COSV52317208; called by muse, mutect2, varscan2
- AFM | c.843G>A p.T281= | Splice Region (SNP) | VAF 25/98 reads (26%) | catalogued as rs752151201, COSV99888661; called by muse, mutect2, varscan2
- AFMID | c.72G>T p.E24D | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs576783336, COSV56961441; called by mutect2, varscan2
- AFTPH | c.389G>T p.R130I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV53221779; called by muse, mutect2, varscan2
- AGAP1 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.736); catalogued as COSV58338374; called by muse, mutect2, varscan2
- AGAP1 | c.2497C>T p.L833F (on ENST00000304032 / NM_001037131.3; = p.L780F on NM_014914.5) | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as COSV58338379; called by muse, mutect2, varscan2
- AGBL1 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.534); catalogued as rs201541206; called by muse, mutect2, varscan2
- AGBL1 | c.2405G>A p.R802Q | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs929491552, COSV66869099; called by muse, mutect2
- AGBL3 | c.768G>A p.W256* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | catalogued as COSV51957707; called by muse, mutect2, varscan2
- AGBL4 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs369139471; called by muse, varscan2
- AGGF1 | c.1448A>C p.N483T | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57231123; called by muse, mutect2, varscan2
- AGGF1 | c.1703A>C p.K568T | Missense Mutation (SNP) | VAF 64/372 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57231129; called by muse, mutect2, varscan2
- AGGF1 | c.1811T>C p.F604S | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1413770685, COSV57230524; called by muse, mutect2
- AGL | c.3757C>T p.R1253C | Missense Mutation (SNP) | VAF 52/229 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs375531470; called by muse, varscan2
- AGMO | c.682A>C p.N228H | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61123261; called by muse, mutect2, varscan2
- AGO3 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 10/100 reads (10%) | catalogued as COSV55796866; called by muse, mutect2
- AGO3 | c.2042T>G p.L681* | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | catalogued as COSV55796885; called by muse, mutect2, varscan2
- AGTPBP1 | c.1179T>G p.N393K (on ENST00000357081 / NM_001330701.2; = p.N353K on NM_015239.2) | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61277018; called by muse, mutect2, varscan2
- AGTR2 | c.216A>C p.Q72H | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as COSV64157004; called by muse, mutect2, varscan2
- AGXT2 | c.453G>T p.E151D | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.524); catalogued as COSV51490389; called by muse, mutect2, varscan2
- AHCTF1 | c.6000T>G p.F2000L (on ENST00000366508; = p.F1974L on NM_015446.5) | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100404376; called by muse, varscan2
- AHCTF1 | c.4961A>G p.N1654S (on ENST00000366508; = p.N1628S on NM_015446.5) | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV58254798; called by muse, mutect2, varscan2
- AHCTF1 | c.626A>G p.D209G (on ENST00000366508; = p.D183G on NM_015446.5) | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV58254825; called by muse, mutect2, varscan2
- AHCYL2 | c.534G>T p.K178N | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs201615414, COSV61487208; called by muse, varscan2
- AHI1 | c.455C>A p.S152Y | Missense Mutation (SNP) | VAF 33/313 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs551136002, COSV55627183; called by muse, mutect2, varscan2
- AHNAK | c.14876A>G p.D4959G | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as COSV57229043; called by muse, mutect2, varscan2
- AHNAK | c.6957C>A p.F2319L | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV57229064; called by muse, mutect2, varscan2
- AHNAK | c.2491A>G p.N831D | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as COSV57229080; called by muse, mutect2, varscan2
- AIDA | c.899A>G p.H300R | Missense Mutation (SNP) | VAF 22/325 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.054); catalogued as rs1345937836; called by muse, mutect2
- AIP | c.190A>G p.I64V | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV54161807; called by muse, mutect2, varscan2
- AK7 | c.1385G>T p.R462I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV50881758; called by muse, mutect2, varscan2
- AKAP11 | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1566270972, COSV50302016; called by muse, mutect2, varscan2
- AKAP11 | c.1813T>C p.F605L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.436); catalogued as COSV50302037; called by mutect2, varscan2
- AKAP11 | c.4978G>T p.E1660* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | catalogued as COSV50302058; called by muse, mutect2, varscan2
- AKAP13 | c.5522T>C p.V1841A (on ENST00000394518 / NM_007200.5; = p.V1845A on NM_006738.6) | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV63468936; called by muse, varscan2
- AKAP13 | c.6976C>A p.Q2326K (on ENST00000394518 / NM_007200.5; = p.Q2330K on NM_006738.6) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV100774560; called by mutect2, varscan2
- AKAP14 | c.520A>C p.N174H | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV57631279; called by muse, mutect2, varscan2
- AKAP4 | c.1913T>G p.L638R | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV62075408; called by muse, mutect2, varscan2
- AKAP4 | c.442C>A p.H148N | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV62075409; called by muse, mutect2, varscan2
- AKAP6 | c.4955G>A p.R1652Q | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763532229, COSV55208487; called by muse, mutect2, varscan2
- AKAP9 | c.882C>A p.F294L | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.035); catalogued as COSV62357061; called by muse, mutect2, varscan2
- AKAP9 | c.2309T>G p.F770C | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV62357086; called by muse, mutect2, varscan2
- AKAP9 | c.11206C>T p.R3736* (on ENST00000359028; = p.R3712* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/63 reads (17%) | catalogued as rs1234676587, COSV62354774; called by muse, mutect2, varscan2
- AKNA | c.861C>A p.F287L | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56314842; called by muse, mutect2, varscan2
- AKR1B15 | c.873G>T p.K291N | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV71152743; called by muse, varscan2
- AKR1D1 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs148732404; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKT3 | c.1056G>T p.E352D | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.046); catalogued as COSV55631438; called by muse, mutect2, varscan2
- AL136295.1 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.535); catalogued as rs756204607, COSV55780544; called by muse, mutect2, varscan2
- AL645922.1 | c.88A>G p.I30V | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV54962411; called by muse, mutect2, varscan2
- ALAS2 | c.935A>C p.K312T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.281); catalogued as COSV58193128; called by muse, mutect2
- ALAS2 | c.933G>T p.K311N | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100238556, COSV58189379; called by muse, mutect2
- ALB | c.495A>C p.E165D | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as COSV55742126; called by muse, mutect2, varscan2
- ALB | c.1194C>T p.F398= | Splice Region (SNP) | VAF 26/112 reads (23%) | catalogued as rs770952660, COSV55735522, COSV55737469; ClinVar: uncertain significance; called by muse, varscan2
- ALCAM | c.174T>G p.Y58* | Nonsense Mutation (SNP) | VAF 14/137 reads (10%) | catalogued as COSV60254399; called by muse, varscan2
- ALCAM | c.1120C>T p.R374* | Nonsense Mutation (SNP) | VAF 22/274 reads (8%) | catalogued as rs1448199395, COSV60250831; called by muse, mutect2
- ALDH9A1 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs201328563; called by muse, varscan2
- ALG10 | c.895C>A p.L299I | Missense Mutation (SNP) | VAF 62/348 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as COSV56792691, COSV56794086; called by muse, mutect2, varscan2
- ALG13 | c.316A>C p.N106H | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.971); catalogued as rs1273593358, COSV52644697; called by muse, mutect2, varscan2
- ALG13 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.761); catalogued as COSV52644716; called by muse, mutect2, varscan2
- ALG13 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | catalogued as COSV52634896; called by muse, mutect2, varscan2
- ALG1L2 | c.229C>A p.L77M | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV101405959; called by mutect2, varscan2
- ALG6 | c.464G>A p.G155D | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54767622; called by muse, mutect2, varscan2
- ALG8 | c.571C>A p.L191I | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.665); catalogued as COSV55202851; called by muse, mutect2, varscan2
- ALK | c.1616T>G p.F539C | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV66588168; called by muse, mutect2, varscan2
- ALLC | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs757104090, COSV52993453; called by muse, mutect2, varscan2
- ALMS1 | c.6894G>T p.K2298N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); catalogued as COSV52520982; called by muse, mutect2, varscan2
- ALMS1 | c.7552A>C p.K2518Q | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52520990; called by muse, mutect2, varscan2
- ALMS1 | c.10516T>G p.F3506V | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV52521002; called by muse, mutect2, varscan2
- ALOX5 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | catalogued as COSV65553390, COSV65554102; called by muse, mutect2, varscan2
- ALS2 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV51892108, COSV99969199; called by muse, mutect2, varscan2
- ALX1 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs144593505; called by muse, mutect2, varscan2
- AMER1 | c.2825G>A p.R942Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs368031008, COSV57667499, COSV57668145; called by mutect2, varscan2
- AMER1 | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 13/27 reads (48%) | catalogued as COSV100365954, COSV57667509; called by muse, mutect2, varscan2
- AMER2 | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as COSV100766376; called by muse, mutect2
- AMER3 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1381313687, COSV58465747; called by muse, mutect2, varscan2
- AMIGO3 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV57537835; called by muse, mutect2, varscan2
- ANAPC1 | c.1388A>C p.K463T | Missense Mutation (SNP) | VAF 50/287 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV61979279; called by muse, mutect2, varscan2
- ANAPC4 | c.133T>G p.L45V | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.949); catalogued as COSV59546047; called by muse, mutect2, varscan2
- ANAPC4 | c.1856A>C p.K619T | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV59546057; called by muse, mutect2, varscan2
- ANGEL1 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781341904, COSV51875409; called by muse, mutect2, varscan2
- ANGPT2 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.742); catalogued as COSV57340137; called by muse, mutect2, varscan2
- ANGPT4 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67922773; called by muse, mutect2, varscan2
- ANGPTL5 | c.233T>G p.F78C | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.237); catalogued as rs1443023349, COSV57534515; called by muse, mutect2, varscan2
- ANK1 | c.4958C>A p.S1653Y | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.013); catalogued as COSV55874964; called by muse, mutect2, varscan2
- ANK1 | c.4727C>A p.S1576Y | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.729); catalogued as COSV55894766; called by muse, mutect2, varscan2
- ANK1 | c.211C>A p.L71I | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as COSV55894778; called by muse, mutect2, varscan2
- ANK2 | c.6205C>T p.R2069C | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.736); catalogued as rs754572911, COSV52159875, COSV52189518; called by muse, mutect2, varscan2
- ANK2 | c.8489C>A p.S2830Y | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.66); catalogued as COSV52186079; called by muse, mutect2, varscan2
- ANK2 | c.9593C>A p.A3198D | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.075); catalogued as COSV52158978, COSV52186093; called by muse, mutect2, varscan2
- ANK2 | c.10966C>T p.L3656F | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.888); catalogued as COSV52186115; called by muse, mutect2, varscan2
- ANK3 | c.12917C>A p.S4306Y (on ENST00000280772 / NM_001320874.2; = p.S930Y on NM_001149.3) | Missense Mutation (SNP) | VAF 27/247 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.161); catalogued as COSV55051539, COSV55079656; called by muse, mutect2, varscan2
- ANK3 | c.11422C>A p.L3808M | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.372); catalogued as rs1475431412, COSV55079672; called by muse, mutect2, varscan2
- ANK3 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 31/216 reads (14%) | catalogued as COSV55079698; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.962T>C p.V321A | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV51857547; called by muse, mutect2, varscan2
- ANKIB1 | c.1670C>T p.S557L | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56065757; called by muse, mutect2, varscan2
- ANKK1 | c.1410G>T p.Q470H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs772246720, COSV58274113; called by muse, mutect2, varscan2
- ANKRD11 | c.3533A>G p.D1178G | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); catalogued as rs1447641697; called by muse, mutect2, varscan2
- ANKRD11 | c.3201A>C p.K1067N | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99970487; called by mutect2, varscan2
- ANKRD12 | c.452-1G>T p.X151_splice | Splice Site (SNP) | VAF 18/127 reads (14%) | catalogued as COSV50845826; called by muse, mutect2, varscan2
- ANKRD17 | c.5843G>A p.R1948H | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1460027797, COSV58227236; called by muse, varscan2
- ANKRD17 | c.5254C>T p.R1752W | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1367782921, COSV58216120; called by muse, mutect2, varscan2
- ANKRD17 | c.2479G>T p.E827* | Nonsense Mutation (SNP) | VAF 30/276 reads (11%) | catalogued as COSV58217567; called by muse, mutect2
- ANKRD18B | c.389A>C p.K130T | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV52093181; called by muse, mutect2, varscan2
- ANKRD18B | c.2383G>T p.E795* | Nonsense Mutation (SNP) | VAF 19/325 reads (6%) | catalogued as COSV52091714; called by muse, mutect2
- ANKRD30A | c.1110G>T p.E370D (on ENST00000611781; = p.E314D on NM_052997.2) | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.899); catalogued as COSV64620125; called by muse, mutect2, varscan2
- ANKRD30A | c.1204A>G p.T402A (on ENST00000611781; = p.T346A on NM_052997.2) | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.217); catalogued as COSV64607716; called by muse, mutect2, varscan2
- ANKRD30A | c.3415T>G p.L1139V (on ENST00000611781; = p.L1083V on NM_052997.2) | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as COSV64620142; called by muse, mutect2, varscan2
- ANKRD30B | c.581A>C p.K194T | Missense Mutation (SNP) | VAF 37/293 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV62822704; called by muse, mutect2, varscan2
- ANKRD30B | c.2789G>A p.G930D | Missense Mutation (SNP) | VAF 48/461 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.934); catalogued as COSV100271663; called by muse, mutect2, varscan2
- ANKRD30BL | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0.031); catalogued as rs1558914912, COSV99724555; called by muse, mutect2
- ANKRD36 | c.374A>C p.N125T | Missense Mutation (SNP) | VAF 86/882 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV70745033; called by muse, mutect2, varscan2
- ANKRD36B | c.1661A>C p.D554A | Missense Mutation (SNP) | VAF 67/646 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV51536845; called by muse, mutect2, varscan2
- ANKRD36B | c.726A>C p.R242S | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV51536850; called by muse, varscan2
- ANKRD42 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.319); catalogued as rs780800417, COSV52615647; called by mutect2, varscan2
- ANKRD44 | c.2670T>G p.I890M | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV56565072; called by muse, mutect2, varscan2
- ANKRD6 | c.2072G>A p.R691Q (on ENST00000339746 / NM_001242809.2; = p.R686Q on NM_014942.4) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs747160750, COSV100329340; called by mutect2, varscan2
- ANKS1A | c.1309T>C p.S437P | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV100832805; called by muse, mutect2, varscan2
- ANKS1B | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.038); catalogued as COSV61374262; called by muse, mutect2
- ANKS1B | c.1023G>T p.K341N | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV61381694; called by muse, mutect2, varscan2
- ANO1 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768285449, COSV60288936; called by mutect2, varscan2
- ANO1 | c.2785C>A p.L929I | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.411); catalogued as COSV62449655; called by muse, mutect2, varscan2
- ANO10 | c.1342G>T p.E448* | Nonsense Mutation (SNP) | VAF 16/91 reads (18%) | catalogued as COSV52735956; called by muse, mutect2, varscan2
- ANO2 | c.2675C>T p.S892L (on ENST00000356134 / NM_001278597.3; = p.S896L on NM_001278596.3) | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767967144, COSV59020201, COSV59035280; called by muse, mutect2, varscan2
- ANO2 | c.1274C>T p.T425I (on ENST00000356134 / NM_001278597.3; = p.T429I on NM_001278596.3) | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.872); catalogued as COSV59041543; called by muse, mutect2, varscan2
- ANO3 | c.43A>C p.K15Q | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.966); catalogued as COSV56807399; called by muse, mutect2, varscan2
- ANO4 | c.2338C>T p.L780F (on ENST00000392977 / NM_001286615.2; = p.L745F on NM_178826.4) | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV54592579, COSV54594505; called by muse, mutect2, varscan2
- ANO4 | c.2746C>T p.R916* (on ENST00000392977 / NM_001286615.2; = p.R881* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 9/127 reads (7%) | catalogued as rs778663996, COSV54617991; called by muse, mutect2
- ANO5 | c.337C>A p.L113I | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61083785, COSV61087223; called by muse, varscan2
- ANO5 | c.721C>A p.L241I | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.589); catalogued as COSV61089932; called by muse, mutect2, varscan2
- ANPEP | c.1972C>T p.R658W | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866441038, COSV55594662; called by muse, mutect2, varscan2
- ANTXR1 | c.707C>A p.S236* | Nonsense Mutation (SNP) | VAF 19/66 reads (29%) | catalogued as COSV58021160; called by muse, mutect2, varscan2
- ANTXR2 | c.1172G>T p.R391I | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56319488; called by muse, mutect2, varscan2
- ANTXR2 | c.293A>G p.D98G | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV55020758; called by muse, mutect2, varscan2
- ANXA1 | c.831C>A p.F277L | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV57412629, COSV57413269; called by muse, mutect2, varscan2
- ANXA1 | c.881A>G p.K294R | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as COSV57412637; called by muse, varscan2
- ANXA3 | c.300G>T p.K100N | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.47); catalogued as COSV53714695, COSV53717228; called by muse, mutect2, varscan2
- ANXA6 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1233962893, COSV62908283; called by muse, mutect2, varscan2
- ANXA9 | c.807G>T p.K269N | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV64485554; called by muse, mutect2, varscan2
- AOC2 | c.1303C>T p.R435* | Nonsense Mutation (SNP) | VAF 18/73 reads (25%) | catalogued as rs777111912, COSV53200278; called by muse, mutect2, varscan2
- AOC2 | c.1790G>A p.R597H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs780166614, COSV104389486, COSV53826786; called by mutect2, varscan2
- AOC3 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV53827684, COSV53828686; called by muse, mutect2
- AOPEP | c.385A>C p.K129Q | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.215); catalogued as COSV99469397; called by muse, mutect2, varscan2
- AOX1 | c.860C>A p.S287Y | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.224); catalogued as COSV65980758; called by muse, mutect2, varscan2
- AP1G1 | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55494816; called by muse, mutect2, varscan2
- AP1G1 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as COSV55492956; called by muse, mutect2, varscan2
- AP1M1 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.089); catalogued as rs1218074745, COSV52228789; called by muse, mutect2, varscan2
- AP2A1 | c.310T>C p.S104P | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV62820850; called by muse, mutect2, varscan2
- AP2B1 | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 12/84 reads (14%) | catalogued as rs1404738425, COSV51997738; called by muse, varscan2
- AP3B1 | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 38/164 reads (23%) | catalogued as COSV54892156; called by muse, varscan2
- AP3M1 | c.1183T>C p.Y395H | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.078); catalogued as COSV53014351; called by muse, mutect2
- AP3M2 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142101815, COSV51527608; called by mutect2, varscan2
- AP4B1 | c.2150C>T p.T717M | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as rs199879996; called by muse, mutect2, varscan2
- AP4E1 | c.602A>G p.N201S | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.191); catalogued as COSV55919855; called by muse, varscan2
- APBB1 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.14); catalogued as rs561124514, COSV100194300; called by mutect2, varscan2
- APC | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 8/88 reads (9%) | catalogued as rs1314843920, CM013690, COSV57335557; called by muse, mutect2
- APC | c.2414G>A p.R805Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.953); catalogued as rs200593940, COSV57349131, COSV57385162; ClinVar: uncertain significance; called by mutect2, varscan2
- APC | c.4706A>C p.D1569A | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV57379510; called by muse, mutect2, varscan2
- APC | c.6920C>T p.S2307L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs901983934, COSV57330138; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APH1B | c.275A>C p.K92T | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as COSV56015293; called by mutect2, varscan2
- APLP1 | c.1664T>C p.V555A (on ENST00000221891 / NM_001024807.3; = p.V554A on NM_005166.4) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV99697907; called by muse, mutect2, varscan2
- APOB | c.13527C>A p.Y4509* | Nonsense Mutation (SNP) | VAF 17/123 reads (14%) | catalogued as COSV51950815; called by muse, mutect2, varscan2
- APOB | c.12491T>C p.F4164S | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV99267807; called by mutect2, varscan2
- APOB | c.10508C>T p.S3503L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as rs375284245, CM088504; ClinVar: uncertain significance; called by mutect2, varscan2
- APOB | c.7060A>C p.I2354L | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV51950869; called by muse, mutect2, varscan2
- APOB | c.4648C>A p.L1550M | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51935541; called by muse, varscan2
- APOB | c.2051C>A p.S684* | Nonsense Mutation (SNP) | VAF 10/73 reads (14%) | catalogued as COSV51950884; called by muse, mutect2, varscan2
- APOB | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as COSV104373561, COSV51950894; called by muse, varscan2
- APOBEC1 | c.270G>A p.W90* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as COSV57550087; called by muse, varscan2
- APOBEC3F | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.949); catalogued as rs761754118, COSV57909966; called by mutect2, varscan2
- APOBEC4 | c.287C>A p.S96* | Nonsense Mutation (SNP) | VAF 40/162 reads (25%) | catalogued as COSV58018476; called by muse, mutect2, varscan2
- APPL1 | c.1450G>T p.E484* | Nonsense Mutation (SNP) | VAF 19/81 reads (23%) | catalogued as COSV55703394; called by muse, mutect2, varscan2
- APPL1 | c.1511T>C p.V504A | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs368758377; called by mutect2, varscan2
- APPL2 | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 11/84 reads (13%) | catalogued as COSV51593514; called by muse, mutect2, varscan2
- AQP4 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs372185576; called by muse, varscan2
- AQP4 | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as COSV67219360; called by muse, mutect2, varscan2
- AQP5 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.925); catalogued as rs532533853, COSV52231838; called by muse, mutect2, varscan2
- AQR | c.1180G>T p.E394* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV50029656; called by muse, mutect2, varscan2
- AQR | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 24/163 reads (15%) | catalogued as COSV50032461; called by muse, mutect2, varscan2
- AQR | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs376460301; called by muse, mutect2, varscan2
- AR | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV65955976; called by muse, mutect2, varscan2
- AR | c.2569T>G p.F857V | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101019383; called by muse, mutect2, varscan2
- ARAF | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 6/13 reads (46%) | catalogued as COSV51692980; called by muse, mutect2, varscan2
- ARAP1 | c.2882C>T p.S961L (on ENST00000393609 / NM_001040118.2; = p.S716L on NM_015242.4) | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs1016634725, COSV61994742; called by muse, mutect2, varscan2
- ARAP2 | c.4063G>A p.E1355K | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1560459149; called by muse, mutect2, varscan2
- ARAP2 | c.830G>T p.R277I | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV58291664; called by muse, mutect2, varscan2
- ARFGEF1 | c.5320C>T p.R1774* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as COSV51588024; called by muse, mutect2, varscan2
- ARFGEF1 | c.1442T>G p.I481S | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51616531; called by muse, mutect2, varscan2
- ARFGEF2 | c.3372G>T p.M1124I | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV64214874; called by muse, mutect2
- ARFIP1 | c.572A>G p.H191R (on ENST00000353617 / NM_001287432.1; = p.H159R on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV61886155; called by muse, mutect2, varscan2
- ARGFX | c.372T>C p.V124= | Splice Region (SNP) | VAF 8/49 reads (16%) | catalogued as COSV57683637; called by muse, mutect2, varscan2
- ARHGAP12 | c.1970A>C p.N657T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.114); catalogued as COSV60966064; called by muse, mutect2, varscan2
- ARHGAP12 | c.1452G>T p.K484N | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV60962390; called by muse, mutect2, varscan2
- ARHGAP12 | c.326A>C p.K109T | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as COSV60966078; called by muse, mutect2, varscan2
- ARHGAP15 | c.447A>C p.E149D | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV54519351; called by muse, mutect2, varscan2
- ARHGAP18 | c.540A>C p.E180D | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV63766080; called by muse, mutect2, varscan2
- ARHGAP20 | c.3264G>T p.E1088D | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV52818618; called by muse, mutect2, varscan2
- ARHGAP20 | c.2392C>T p.P798S | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.139); catalogued as rs751028197, COSV52818636, COSV99505332; called by muse, mutect2, varscan2
- ARHGAP21 | c.3178G>T p.E1060* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV57601656, COSV57609108; called by mutect2, varscan2
- ARHGAP29 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 10/53 reads (19%) | catalogued as COSV53116450; called by muse, mutect2, varscan2
- ARHGAP35 | c.2812T>G p.F938V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs928875560, COSV68335453; called by muse, mutect2, varscan2
- ARHGAP36 | c.-145G>A | Splice Region (SNP) | VAF 9/52 reads (17%) | catalogued as rs1024165725, COSV99357667; called by muse, varscan2
- ARHGAP40 | c.1271T>C p.V424A | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV54810195; called by muse, mutect2, varscan2
- ARHGAP42 | c.113A>G p.E38G | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV53986088; called by muse, mutect2, varscan2
- ARHGAP42 | c.977C>A p.S326Y | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.041); catalogued as COSV53986099; called by muse, mutect2, varscan2
- ARHGAP45 | c.2615G>A p.R872Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.641); catalogued as rs1407666349, COSV57436084; called by muse, mutect2
- ARHGAP5 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61539139; called by muse, mutect2, varscan2
- ARHGAP5 | c.3689A>C p.K1230T | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.991); catalogued as COSV61539144; called by muse, mutect2, varscan2
- ARHGAP6 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs1569233984, COSV57294006; called by muse, mutect2, varscan2
- ARHGDIB | c.333T>G p.I111M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57457323; called by muse, mutect2, varscan2
- ARHGEF10 | c.3006T>G p.I1002M (on ENST00000398564; = p.I977M on NM_014629.4) | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV50674883; called by muse, varscan2
- ARHGEF10 | c.3011A>C p.K1004T (on ENST00000398564; = p.K979T on NM_014629.4) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV50675003; called by muse, varscan2
- ARHGEF15 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); catalogued as COSV100730149; called by muse, mutect2
- ARHGEF17 | c.2444A>G p.D815G | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); catalogued as COSV55237610; called by muse, mutect2, varscan2
- ARHGEF26 | c.1114G>T p.D372Y | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV62844654; called by muse, mutect2, varscan2
- ARHGEF26 | c.1486A>C p.K496Q | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV62851599; called by muse, mutect2, varscan2
- ARHGEF28 | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV55268462; called by muse, mutect2, varscan2
- ARHGEF3 | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.715); catalogued as rs764625854, COSV56332102; called by mutect2, varscan2
- ARHGEF3 | c.117G>A p.W39* | Nonsense Mutation (SNP) | VAF 16/97 reads (16%) | catalogued as COSV58190720; called by muse, mutect2, varscan2
- ARHGEF33 | c.1048G>T p.D350Y | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV67258169; called by muse, mutect2, varscan2
- ARHGEF6 | c.1883A>C p.K628T | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51695784; called by muse, mutect2, varscan2
- ARID1A | c.6043A>T p.I2015F | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV61388313; called by muse, mutect2, varscan2
- ARID1B | c.1978G>T p.E660* | Nonsense Mutation (SNP) | VAF 10/118 reads (8%) | catalogued as rs1477561038; called by muse, mutect2
- ARID3C | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV52406925; called by muse, mutect2
- ARID5B | c.259A>T p.N87Y | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV54420615; called by muse, mutect2, varscan2
- ARIH1 | c.906A>C p.Q302H | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.814); catalogued as COSV65912912; called by muse, mutect2, varscan2
- ARL13B | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs887056386, COSV57397826; called by muse, mutect2
- ARL13B | c.656G>T p.R219I (on ENST00000394222 / NM_001174150.2; = p.R112I on NM_144996.4) | Missense Mutation (SNP) | VAF 19/232 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV57401286; called by muse, mutect2
- ARL4A | c.368A>C p.E123A | Missense Mutation (SNP) | VAF 30/281 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.083); catalogued as COSV63319606; called by muse, mutect2, varscan2
- ARL6 | c.424A>C p.K142Q | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV60118890; called by muse, mutect2, varscan2
- ARL6IP5 | c.551G>A p.S184N | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs757868106, COSV56235673; called by mutect2, varscan2
- ARMC1 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1259809049, COSV52533839, COSV52534776; called by muse, mutect2, varscan2
- ARMC3 | c.1966C>A p.P656T | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV53067124; called by muse, mutect2, varscan2
- ARMC3 | c.2393G>A p.R798Q | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372574174; called by mutect2, varscan2
- ARMCX1 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as rs1556027234, COSV65705516; called by muse, mutect2, varscan2
- ARMCX1 | c.980A>G p.Y327C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as rs1556027479, COSV65705523; called by muse, mutect2, varscan2
- ARMCX3 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV57871559; called by muse, mutect2, varscan2
- ARMT1 | c.44C>A p.S15* | Nonsense Mutation (SNP) | VAF 15/70 reads (21%) | catalogued as COSV66179069; called by muse, mutect2, varscan2
- ARNT2 | c.1015T>C p.S339P | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57590193; called by muse, mutect2, varscan2
- ARNTL2 | c.1587-1G>T p.X529_splice | Splice Site (SNP) | VAF 14/166 reads (8%) | catalogued as COSV99668055; called by muse, mutect2
- ARPC3 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV57400508; called by muse, mutect2, varscan2
- ARPC5L | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV99414604; called by mutect2, varscan2
- ARPIN | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1339904406, COSV62589922; called by muse, varscan2
- ARPP21 | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 24/79 reads (30%) | catalogued as COSV51794552, COSV51810314; called by muse, mutect2, varscan2
- ARPP21 | c.1997G>A p.R666K | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as COSV51798003; called by muse, mutect2, varscan2
- ARRDC3 | c.146T>G p.I49S | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV54366434; called by muse, mutect2, varscan2
- ARSJ | c.1722G>T p.K574N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs778014769, COSV59539640; called by mutect2, varscan2
- ASAH2 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs766598373, COSV61482783; called by muse, mutect2, varscan2
- ASAH2B | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 53/418 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs551101710, COSV51768400; called by muse, varscan2
- ASAP1 | c.90C>A p.F30L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1276588252; called by muse, mutect2, varscan2
- ASAP2 | c.1565G>T p.R522I | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55638098; called by muse, mutect2, varscan2
- ASB11 | c.316T>C p.C106R | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs767895073, COSV60356526; called by mutect2, varscan2
- ASB11 | c.34A>C p.N12H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.995); catalogued as COSV60356536; called by muse, mutect2, varscan2
- ASH1L | c.3620A>C p.N1207T | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV64213238; called by muse, mutect2, varscan2
- ASH1L | c.3038A>C p.K1013T | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.614); catalogued as COSV64213246; called by muse, mutect2, varscan2
- ASH1L | c.1624A>G p.T542A | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.098); catalogued as COSV64213253; called by muse, mutect2, varscan2
- ASMT | c.760C>A p.L254I (on ENST00000381229; = p.L282I on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/256 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.779); catalogued as COSV67110337; called by muse, mutect2, varscan2
- ASPM | c.6380T>C p.F2127S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54137930; called by muse, mutect2, varscan2
- ASPM | c.4009A>C p.M1337L | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as COSV54137942; called by muse, varscan2
- ASTN1 | c.3493A>C p.N1165H | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62505505; called by muse, mutect2
- ASXL3 | c.933C>A p.F311L | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52465157; called by muse, mutect2, varscan2
- ASXL3 | c.1154C>A p.S385Y | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as COSV52461178; called by muse, varscan2
- ASXL3 | c.2158T>C p.S720P | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52461529; called by muse, mutect2, varscan2
- ASXL3 | c.3704C>T p.S1235F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.201); catalogued as COSV52461645, COSV52474635; called by muse, mutect2, varscan2
- ASZ1 | c.336A>C p.Q112H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs750511705, COSV52916248; called by muse, mutect2, varscan2
- ATAD2B | c.2762G>A p.R921Q | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.796); catalogued as rs952541811; called by muse, mutect2
- ATAD2B | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV53198340; called by muse, mutect2, varscan2
- ATAD2B | c.785-1G>T p.X262_splice | Splice Site (SNP) | VAF 46/172 reads (27%) | catalogued as COSV53204906; called by muse, mutect2, varscan2
- ATAD5 | c.3797C>A p.S1266Y | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV100429935; called by muse, mutect2
- ATAD5 | c.5404C>T p.R1802* | Nonsense Mutation (SNP) | VAF 20/77 reads (26%) | catalogued as rs1388273738, COSV58972671, COSV58977524; called by muse, mutect2, varscan2
- ATF6B | c.1640C>T p.P547L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV64352602; called by muse, mutect2, varscan2
- ATG13 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as rs759630324, COSV56317809; called by mutect2, varscan2
- ATG16L1 | c.1429C>T p.R477* (on ENST00000392017 / NM_030803.7; = p.R458* on NM_017974.4) | Nonsense Mutation (SNP) | VAF 21/87 reads (24%) | catalogued as COSV61464147, COSV61468342; called by muse, mutect2, varscan2
- ATG2B | c.4987T>G p.L1663V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV55889884; called by muse, mutect2, varscan2
- ATG2B | c.3154C>A p.L1052I | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as COSV63422145, COSV63424081; called by muse, mutect2, varscan2
- ATG4C | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.059); catalogued as rs759584462, COSV58606506; called by mutect2, varscan2
- ATL1 | c.203T>G p.V68G | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV63297598; called by muse, varscan2
- ATM | c.1834C>A p.L612I | Missense Mutation (SNP) | VAF 43/396 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs747242300, COSV53764037; called by muse, mutect2, varscan2
- ATP10B | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 25/242 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV58781185; called by muse, mutect2, varscan2
- ATP11B | c.2870G>A p.S957N | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.347); catalogued as COSV60033057; called by muse, varscan2
- ATP11C | c.3367C>T p.R1123* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as rs937327259, COSV59563781; called by muse, mutect2, varscan2
- ATP11C | c.490C>A p.L164I | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV59573585; called by muse, mutect2, varscan2
- ATP11C | c.206G>T p.R69I | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59558906, COSV59560563; called by muse, varscan2
- ATP13A4 | c.2094G>T p.E698D | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as COSV61319252; called by muse, varscan2
- ATP13A5 | c.2254G>T p.E752* | Nonsense Mutation (SNP) | VAF 14/86 reads (16%) | catalogued as rs1352082779, COSV60866463; called by muse, mutect2, varscan2
- ATP13A5 | c.185A>G p.N62S | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV100665700; called by muse, mutect2
- ATP1A1 | c.378A>C p.Q126H | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV55194110; called by muse, mutect2, varscan2
- ATP1A2 | c.1705G>A p.D569N | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as rs1409103763, COSV63405744; called by muse, varscan2
- ATP1A2 | c.1724T>C p.F575S | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63405746; called by muse, varscan2
- ATP1A4 | c.1366A>G p.T456A | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV63628378; called by muse, mutect2, varscan2
- ATP1A4 | c.2548C>A p.L850M | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63626754; called by muse, mutect2, varscan2
- ATP1B3 | c.512T>C p.I171T | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV53951541; called by muse, mutect2, varscan2
- ATP2C1 | c.1699A>C p.K567Q | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV60762166; called by muse, mutect2, varscan2
- ATP2C1 | c.1882A>G p.I628V | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV104408834, COSV60762182; called by muse, mutect2, varscan2
- ATP4A | c.1191G>T p.M397I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52871573; called by muse, varscan2
- ATP4A | c.1145C>T p.S382L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs908819738, COSV52871584; called by muse, varscan2
- ATP6AP2 | c.406A>G p.M136V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as COSV65798294; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2156T>G p.V719G | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV59479969; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1987A>G p.R663G | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.967); catalogued as COSV59479980; called by muse, mutect2, varscan2
- ATP6V1A | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs922143048, COSV56360731, COSV56364398; called by muse, mutect2, varscan2
- ATP6V1H | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 32/160 reads (20%) | catalogued as COSV62217366; called by muse, varscan2
- ATP7A | c.2957G>A p.R986Q | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.24); PolyPhen probably damaging (1); catalogued as rs781995242, CM078711, COSV58442198; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP7B | c.3467G>A p.R1156H | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773917820, CM080088, COSV54435085; ClinVar: uncertain significance; called by mutect2, varscan2
- ATP7B | c.1880T>G p.F627C | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54443639; called by muse, mutect2, varscan2
- ATP7B | c.1028C>A p.S343Y | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.035); catalogued as COSV54437593, COSV54443649; called by muse, mutect2, varscan2
- ATP8A1 | c.1768G>T p.E590* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV52539605, COSV52544554; called by muse, mutect2, varscan2
- ATP8A2 | c.643A>C p.I215L | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV54975281; called by muse, mutect2, varscan2
- ATP8A2 | c.915G>T p.K305N | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54945829; called by muse, mutect2, varscan2
- ATP8B1 | c.716T>G p.F239C | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV52179796; called by muse, mutect2, varscan2
- ATP8B2 | c.2153G>A p.G718D (on ENST00000672630; = p.G685D on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59248693; called by muse, mutect2, varscan2
- ATP8B2 | c.2344G>A p.V782I (on ENST00000672630; = p.V749I on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as rs753821662, COSV59248695; called by muse, mutect2, varscan2
- ATP8B4 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV52726399; called by muse, varscan2
- ATR | c.4784A>C p.K1595T | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.321); catalogued as COSV63385971, COSV63391807; called by muse, mutect2, varscan2
- ATR | c.3802C>T p.L1268F | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1383288417; called by muse, mutect2, varscan2
- ATR | c.3715A>C p.I1239L | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV63391859; called by muse, varscan2
- ATR | c.3232G>T p.E1078* | Nonsense Mutation (SNP) | VAF 12/89 reads (13%) | catalogued as COSV63391866; called by muse, mutect2, varscan2
- ATRNL1 | c.2377G>T p.E793* | Nonsense Mutation (SNP) | VAF 7/68 reads (10%) | catalogued as COSV61816686; called by muse, mutect2, varscan2
- ATRNL1 | c.3085G>A p.E1029K | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs781814300, COSV100369594, COSV58087049; called by muse, mutect2, varscan2
- ATRNL1 | c.4088C>A p.S1363Y | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.28); catalogued as COSV58113125; called by muse, varscan2
- ATRX | c.6215A>C p.K2072T | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV64882866; called by muse, varscan2
- ATRX | c.2692G>T p.D898Y | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.365); catalogued as COSV100970491, COSV64877609, COSV64882870; called by muse, mutect2, varscan2
- ATRX | c.2209A>G p.I737V | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs782110483, COSV64882879; called by muse, mutect2, varscan2
- ATRX | c.326A>C p.N109T | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV64870057; called by muse, mutect2, varscan2
- ATXN10 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as rs1042452273, COSV53298989, COSV99426550; called by muse, mutect2, varscan2
- ATXN2 | c.1895G>A p.R632Q (on ENST00000550104; = p.R472Q on NM_002973.4) | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV66482110; called by muse, mutect2, varscan2
- ATXN2L | c.1522G>T p.E508* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV57378398; called by muse, mutect2, varscan2
- ATXN7L1 | c.818A>G p.Q273R | Missense Mutation (SNP) | VAF 53/320 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV69308825; called by muse, mutect2, varscan2
- AUTS2 | c.406C>A p.H136N | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.215); catalogued as COSV61428218; called by muse, mutect2, varscan2
- AVIL | c.1565A>C p.K522T | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs768679508, COSV57681178, COSV57683690; called by muse, mutect2, varscan2
- AVPR1A | c.1239C>A p.F413L | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.442); catalogued as rs144329263; called by mutect2, varscan2
- AWAT1 | c.369C>A p.F123L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV65738430, COSV65739014; called by muse, mutect2, varscan2
- AXDND1 | c.907A>G p.I303V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.138); catalogued as rs758873487; called by mutect2, varscan2
- AXIN1 | c.618T>G p.I206M | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV51992907; called by muse, mutect2, varscan2
- AZI2 | c.832T>G p.F278V | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.022); catalogued as COSV55423564; called by muse, mutect2
- B2M | c.358T>C p.*120Qext*6 (on ENST00000559916; = p.*120Qext*48 on NM_004048.4) | Nonstop Mutation (SNP) | VAF 17/96 reads (18%) | catalogued as COSV62566129; called by muse, mutect2, varscan2
- B3GALNT1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs752083614, COSV57581127; called by mutect2, varscan2
- B3GNT2 | c.771T>G p.N257K | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV57345762; called by muse, mutect2, varscan2
- B3GNT4 | c.149G>T p.R50M | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV57336329, COSV57337413; called by mutect2, varscan2
- B4GALT1 | c.918T>G p.N306K | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV65708948; called by muse, mutect2, varscan2
- B4GALT5 | c.472T>C p.C158R | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100867133; called by mutect2, varscan2
- BACH1 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs553355487, COSV54520919; called by muse, mutect2, varscan2
- BACH1 | c.1290G>T p.Q430H | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV54520988; called by muse, mutect2, varscan2
- BAG4 | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 11/94 reads (12%) | catalogued as rs1288051012, COSV54862497; called by muse, mutect2, varscan2
- BAK1 | c.624C>A p.F208L | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as COSV62349920; called by muse, mutect2, varscan2
- BARHL2 | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs780066106, COSV64981980; called by muse, mutect2, varscan2
- BAZ1B | c.2864G>A p.R955H | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.474); catalogued as rs1310053804, COSV59994327; called by muse, mutect2, varscan2
- BAZ2A | c.2228A>C p.K743T | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99467599; called by muse, mutect2, varscan2
- BAZ2B | c.6319T>G p.F2107V | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58609273; called by muse, mutect2, varscan2
- BAZ2B | c.5842C>A p.L1948I | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58602489, COSV58609279; called by muse, mutect2
- BBOX1 | c.192T>G p.I64M | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs1422136484; called by mutect2, varscan2
- BBS2 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99802803; called by muse, mutect2, varscan2
- BBS4 | c.849G>T p.K283N | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99166531; called by muse, mutect2, varscan2
- BBS5 | c.343C>A p.P115T | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); catalogued as COSV54754240; called by muse, mutect2, varscan2
- BBS9 | c.2123C>A p.A708D (on ENST00000242067 / NM_001348036.1; = p.A668D on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.687); catalogued as COSV54185768; called by muse, varscan2
- BBX | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57894078; called by muse, varscan2
- BBX | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 27/108 reads (25%) | catalogued as COSV57894100; called by muse, varscan2
- BCAM | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.355); catalogued as rs569668745, COSV54304706; called by muse, mutect2, varscan2
- BCAR3 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs370899092; called by muse, mutect2, varscan2
- BCAS3 | c.695C>A p.P232H | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66781413; called by muse, mutect2, varscan2
- BCHE | c.1019T>G p.F340C | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52262004; called by muse, mutect2, varscan2
- BCL2A1 | c.422A>C p.E141A | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as COSV51213864; called by muse, mutect2, varscan2
- BCL2A1 | c.375C>A p.F125L | Missense Mutation (SNP) | VAF 47/214 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV51213893; called by muse, mutect2, varscan2
- BCL2L14 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1473390156, COSV53786446; called by muse, mutect2
- BCL2L14 | c.689A>C p.D230A | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV53793654; called by muse, mutect2, varscan2
- BCL2L15 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.038); catalogued as COSV63643302; called by muse, mutect2, varscan2
- BCLAF1 | c.2506G>A p.D836N | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1417547401, COSV50356976; called by muse, mutect2, varscan2
- BCLAF1 | c.1438G>T p.E480* | Nonsense Mutation (SNP) | VAF 21/129 reads (16%) | catalogued as COSV62145516; called by muse, mutect2, varscan2
- BCO2 | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63062697, COSV63064809; called by muse, mutect2, varscan2
- BDKRB1 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145002930, COSV53706253; called by muse, mutect2, varscan2
- BDNF | c.35A>G p.Y12C | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59238157; called by muse, varscan2
- BDP1 | c.1819A>C p.N607H | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as rs773097919, COSV62431094; called by muse, mutect2, varscan2
- BDP1 | c.7617A>C p.R2539S | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs200298842; called by muse, mutect2, varscan2
- BEND2 | c.1733C>A p.S578Y | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.177); catalogued as COSV66217150; called by muse, mutect2, varscan2
- BEND2 | c.1007T>G p.L336* | Nonsense Mutation (SNP) | VAF 41/92 reads (45%) | catalogued as COSV66217775; called by muse, mutect2, varscan2
- BEND5 | c.1006G>T p.D336Y | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV65717429, COSV65718623; called by muse, varscan2
- BEND5 | c.953C>T p.T318I | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs986246171; called by muse, varscan2
- BEX3 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV55420954, COSV55421135; called by muse, mutect2, varscan2
- BFSP1 | c.1118G>T p.R373I | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV100925453; called by muse, mutect2, varscan2
- BFSP2 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 16/92 reads (17%) | catalogued as rs1296755444, COSV56587827; called by muse, mutect2, varscan2
- BIRC2 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.647); catalogued as COSV57163032; called by muse, mutect2, varscan2
- BIRC6 | c.9817G>A p.E3273K | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV70198988; called by muse, mutect2, varscan2
- BIRC7 | c.881G>A p.R294H (on ENST00000217169 / NM_139317.3; = p.R276H on NM_022161.4) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as rs142521563; called by muse, varscan2
- BIVM-ERCC5 | c.195A>C p.K65N | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57282394; called by muse, varscan2
- BIVM-ERCC5 | c.242C>A p.S81* | Nonsense Mutation (SNP) | VAF 29/127 reads (23%) | catalogued as COSV57282404; called by muse, varscan2
- BIVM-ERCC5 | c.1370T>C p.I457T | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.596); catalogued as COSV57282414; called by muse, mutect2
- BLZF1 | c.923C>A p.S308Y | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.534); catalogued as COSV61394811, COSV61395031; called by muse, mutect2, varscan2
- BMP10 | c.563C>A p.S188Y | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54896996; called by muse, mutect2, varscan2
- BMP10 | c.129C>A p.F43L | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.022); catalogued as COSV54897009; called by muse, mutect2, varscan2
- BMP2K | c.2027A>G p.D676G | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.805); catalogued as COSV55011802; called by muse, mutect2, varscan2
- BMPR2 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.542); catalogued as rs397514497, CM085278, COSV65807497; called by muse, mutect2, varscan2
- BMPR2 | c.2339A>G p.N780S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); catalogued as COSV65813306; called by muse, mutect2, varscan2
- BMS1 | c.2494T>G p.L832V | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65735381; called by muse, mutect2, varscan2
- BMT2 | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 28/138 reads (20%) | catalogued as rs376957821; called by muse, varscan2
- BMX | c.597G>T p.K199N | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.101); catalogued as COSV100564652, COSV59593880; called by muse, mutect2, varscan2
- BNC1 | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766072426, COSV61757106, COSV61758012; called by muse, mutect2, varscan2
- BNC2 | c.2748T>G p.F916L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV66175550; called by muse, mutect2, varscan2
- BNC2 | c.191G>T p.R64M | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV66156503; called by muse, mutect2, varscan2
- BOD1L1 | c.2123C>A p.S708Y | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV50034587, COSV99240319; called by muse, mutect2
- BOLL | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs750315080, COSV56577227, COSV99986982; called by muse, mutect2, varscan2
- BPIFB2 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778593567, COSV50070182; called by muse, mutect2, varscan2
- BPIFB6 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs774741947; called by muse, varscan2
- BPNT1 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776487679, COSV59040258; called by mutect2, varscan2
- BPTF | c.586A>G p.S196G | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV100075965; called by muse, mutect2, varscan2
- BPTF | c.2833G>T p.E945* | Nonsense Mutation (SNP) | VAF 26/117 reads (22%) | catalogued as COSV58835826; called by muse, mutect2, varscan2
- BPTF | c.3347A>C p.K1116T | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.154); catalogued as COSV58846023; called by muse, varscan2
- BRAF | c.2029T>C p.S677P (on ENST00000288602 / NM_001374244.1; = p.S637P on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56364152; called by muse, mutect2
- BRAP | c.1330A>C p.K444Q | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59538426; called by muse, mutect2, varscan2
- BRCA1 | c.3953T>C p.I1318T | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs1388475291, COSV58798729; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA1 | c.2069A>G p.K690R | Missense Mutation (SNP) | VAF 29/315 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.819); catalogued as COSV58798745; called by muse, mutect2
- BRCA2 | c.841G>T p.D281Y | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV66447803, COSV66461938; called by muse, mutect2, varscan2
- BRCA2 | c.1334C>A p.S445Y | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs786202373, COSV66461942; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.1838T>G p.L613R | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as rs587780646, COSV66447925, COSV66456161; ClinVar: likely benign / uncertain significance / conflicting interpretations of pathogenicity; called by muse, varscan2
- BRCA2 | c.2701C>A p.L901I | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as CD087315, COSV66461949; called by muse, mutect2, varscan2
- BRCA2 | c.4054G>T p.D1352Y | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs80358655, COSV66461952; ClinVar: uncertain significance / likely benign; called by mutect2, varscan2
- BRCA2 | c.5272A>C p.N1758H | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as CD1410479; called by muse, mutect2, varscan2
- BRCA2 | c.7904A>G p.E2635G | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66461957; called by muse, mutect2, varscan2
- BRD2 | c.344A>G p.K115R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.447); catalogued as rs752802138; called by muse, mutect2
- BRD7 | c.260A>G p.E87G | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV67160007; called by muse, mutect2, varscan2
- BRDT | c.934G>A p.V312I | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142308966, COSV62863712; called by mutect2, varscan2
- BRDT | c.1125G>T p.K375N | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV62867300; called by muse, mutect2, varscan2
- BRDT | c.1377G>T p.K459N | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV62865107; called by muse, mutect2, varscan2
- BRDT | c.2102C>G p.T701R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV62863386; called by muse, mutect2, varscan2
- BRINP1 | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56297833; called by muse, mutect2
- BRINP1 | c.1392G>T p.Q464H | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.857); catalogued as COSV56312282; called by muse, mutect2, varscan2
- BRINP3 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs765103774, COSV66523080; called by muse, mutect2, varscan2
- BRINP3 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV100819480; called by muse, mutect2
- BRIP1 | c.3020C>A p.S1007Y | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.481); catalogued as rs886053214, COSV52008077; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRIP1 | c.1487C>T p.A496V | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as rs1555603612, COSV52008099; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRMS1 | c.213C>A p.F71L | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60820270; called by muse, mutect2, varscan2
- BROX | c.185A>C p.D62A | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.144); catalogued as COSV100572335; called by muse, mutect2, varscan2
- BRPF1 | c.3554G>A p.R1185H | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1400796873, COSV57355058; called by muse, mutect2, varscan2
- BRPF3 | c.2625A>C p.R875S | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV60209602; called by muse, mutect2, varscan2
- BRWD3 | c.1336C>A p.L446I | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.254); catalogued as COSV64753204, COSV64753873; called by muse, mutect2, varscan2
- BSDC1 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs750222067, COSV61981339, COSV61983073; called by mutect2, varscan2
- BSN | c.9996G>T p.E3332D | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV56526644; called by muse, mutect2, varscan2
- BST1 | c.551C>A p.S184Y | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs765296526, COSV53948801, COSV99400178; called by muse, mutect2, varscan2
- BTAF1 | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 9/50 reads (18%) | catalogued as COSV56439125, COSV56439407; called by muse, mutect2, varscan2
- BTBD1 | c.1090T>G p.F364V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99915705; called by mutect2, varscan2
- BTBD11 | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1380156165, COSV55021155; called by muse, mutect2, varscan2
- BTBD16 | c.1181C>T p.S394L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs764340155, COSV53262181; called by mutect2, varscan2
- BTBD18 | c.1127C>A p.P376H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53556205; called by muse, mutect2, varscan2
- BTBD8 | c.1516C>T p.R506C | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1461263445, COSV100952059, COSV64885527; called by muse, mutect2, varscan2
- BTBD8 | c.4139C>A p.S1380Y (on ENST00000636805 / NM_001376131.1; = p.S867Y on NM_015237.4) | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64885530; called by muse, mutect2, varscan2
- BTBD8 | c.4651C>T p.R1551* (on ENST00000636805 / NM_001376131.1; = p.R1038* on NM_015237.4) | Nonsense Mutation (SNP) | VAF 12/83 reads (14%) | catalogued as COSV64885534; called by muse, mutect2, varscan2
- BTBD9 | c.1573T>C p.S525P | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.671); catalogued as COSV100022671; called by muse, mutect2, varscan2
- BTK | c.1807A>G p.N603D | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58123489; called by muse, mutect2, varscan2
- BTK | c.264A>C p.E88D | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV58123497; called by muse, mutect2, varscan2
- BTLA | c.400A>G p.T134A | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as COSV57940495; called by muse, mutect2, varscan2
- BTLA | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 42/241 reads (17%) | catalogued as COSV57937572, COSV57940509; called by muse, mutect2, varscan2
- BTN2A1 | c.236A>C p.K79T | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV57006166; called by muse, mutect2, varscan2
- BTN2A2 | c.180G>T p.E60D | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.593); catalogued as COSV61858599; called by muse, mutect2, varscan2
- BTNL3 | c.998C>A p.S333Y | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV61565793; called by muse, mutect2, varscan2
- BTNL9 | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59799220; called by muse, mutect2, varscan2
- BTRC | c.710C>T p.S237F (on ENST00000370187 / NM_033637.4; = p.S201F on NM_003939.5) | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.289); catalogued as COSV64560475, COSV64560754, COSV64563174; called by muse, mutect2, varscan2
- BTRC | c.1374T>G p.F458L (on ENST00000370187 / NM_033637.4; = p.F422L on NM_003939.5) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as COSV64580855; called by mutect2, varscan2
- BZW1 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV63350347; called by muse, varscan2
- C10orf120 | c.880T>G p.L294V | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1179534178, COSV100271757; called by muse, mutect2, varscan2
- C10orf62 | c.597C>A p.F199L | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV65705546; called by muse, mutect2, varscan2
- C10orf71 | c.2023T>C p.S675P | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60512542; called by muse, mutect2, varscan2
- C11orf53 | c.224T>C p.F75S | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); catalogued as COSV99724891; called by muse, mutect2, varscan2
- C11orf65 | c.108A>C p.K36N | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV67598571; called by muse, mutect2, varscan2
- C12orf40 | c.115T>G p.L39V | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.117); catalogued as COSV61137332; called by muse, varscan2
- C12orf40 | c.1376C>A p.S459Y | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV61130798; called by mutect2, varscan2
- C12orf50 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs776851924, COSV53893621; called by mutect2, varscan2
- C12orf56 | c.1739G>T p.R580M (on ENST00000543942 / NM_001170633.2; = p.R420M on NM_001099676.3) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61489915; called by muse, mutect2, varscan2
- C12orf56 | c.1205G>A p.R402K (on ENST00000543942 / NM_001170633.2; = p.R242K on NM_001099676.3) | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.269); catalogued as COSV61488357; called by muse, varscan2
- C14orf28 | c.186C>A p.F62L | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV57332835, COSV57334153; called by muse, mutect2, varscan2
- C14orf39 | c.423G>T p.K141N | Missense Mutation (SNP) | VAF 47/245 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as rs1566673135, COSV58784788; called by muse, mutect2, varscan2
- C14orf39 | c.224A>C p.N75T | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV58784798; called by muse, mutect2, varscan2
- C16orf71 | c.1280+1G>T p.X427_splice | Splice Site (SNP) | VAF 6/24 reads (25%) | catalogued as COSV54789887; called by muse, mutect2, varscan2
- C16orf89 | c.771C>A p.F257L | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.018); catalogued as COSV60123553; called by muse, mutect2, varscan2
- C16orf96 | c.1591G>T p.D531Y | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); catalogued as COSV71472483; called by muse, mutect2, varscan2
- C17orf67 | c.57G>T p.E19D | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101191007, COSV67375875; called by muse, mutect2
- C19orf12 | c.100G>A p.A34T (on ENST00000392278 / NM_001031726.3; = p.A23T on NM_031448.6) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.481); catalogued as COSV100080645; called by muse, mutect2, varscan2
- C1QL4 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57743392; called by muse, mutect2, varscan2
- C1QTNF9 | c.666A>C p.K222N | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV59658140; called by mutect2, varscan2
- C1orf100 | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 14/77 reads (18%) | catalogued as COSV57374076; called by muse, mutect2, varscan2
- C1orf100 | c.220A>G p.T74A | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.936); catalogued as COSV57374086; called by muse, mutect2, varscan2
- C1orf100 | c.422G>T p.R141I | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1558260625, COSV57372712; called by muse, mutect2, varscan2
- C1orf112 | c.740A>G p.K247R | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs745403386, COSV53682507; called by mutect2, varscan2
- C1orf112 | c.1142A>C p.K381T | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as COSV53682525; called by muse, mutect2, varscan2
- C1orf141 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760295992, COSV63993312; called by mutect2, varscan2
- C1orf141 | c.425C>A p.S142Y | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.906); catalogued as COSV63993156, COSV63993316; called by muse, mutect2, varscan2
- C1orf146 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 17/195 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV64861573; called by muse, mutect2
- C1orf189 | c.268A>C p.N90H | Missense Mutation (SNP) | VAF 25/269 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.653); catalogued as COSV63891287; called by muse, mutect2
- C1orf35 | c.557A>G p.K186R | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV55255919; called by muse, varscan2
- C1orf68 | c.573G>T p.Q191H | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100908949, COSV64224276; called by muse, varscan2
- C1orf68 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs369426180, COSV64224874; called by muse, varscan2
- C1orf74 | c.479G>A p.S160N | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV50559814; called by muse, mutect2, varscan2
- C1orf87 | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.036); catalogued as COSV64598626; called by muse, mutect2, varscan2
- C1orf94 | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.048); catalogued as rs764131580; called by mutect2, varscan2
- C1orf94 | c.422C>A p.S141Y | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.804); catalogued as COSV64915620; called by muse, mutect2, varscan2
- C1orf94 | c.1209G>T p.K403N (on ENST00000488417 / NM_001134734.2; = p.K213N on NM_032884.5) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV64914997, COSV64915624; called by muse, mutect2, varscan2
- C20orf194 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV52702162; called by muse, mutect2, varscan2
- C22orf23 | c.608A>C p.D203A | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50778638; called by muse, mutect2, varscan2
- C2orf16 | c.5156G>A p.R1719H | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs551032627, COSV62678133; called by muse, mutect2, varscan2
- C3 | c.3400C>T p.R1134W | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs138900723; called by muse, mutect2, varscan2
- C3AR1 | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 11/68 reads (16%) | catalogued as rs1233213507; called by muse, mutect2, varscan2
- C3orf38 | c.179T>G p.L60R | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59628946; called by muse, mutect2, varscan2
- C4A | c.3179G>A p.R1060Q | Missense Mutation (SNP) | VAF 65/1207 reads (5%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.983); catalogued as rs749075087, COSV101418359; called by muse, mutect2
- C4orf19 | c.296A>G p.N99S | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as COSV99448768; called by mutect2, varscan2
- C4orf51 | c.192A>C p.Q64H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.371); catalogued as COSV71264640; called by muse, mutect2, varscan2
- C5orf34 | c.1882G>A p.D628N | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749338613, COSV60931544; called by muse, varscan2
- C5orf34 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs751051116, COSV60931222; called by muse, mutect2, varscan2
- C5orf47 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60865377; called by muse, mutect2
- C5orf51 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 14/91 reads (15%) | catalogued as COSV67566394; called by muse, mutect2, varscan2
- C6 | c.2578G>T p.E860* | Nonsense Mutation (SNP) | VAF 16/92 reads (17%) | catalogued as COSV99667135; called by muse, varscan2
- C6 | c.1876G>T p.D626Y | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54708677, COSV54717672; called by muse, mutect2, varscan2
- C6orf58 | c.930A>C p.E310D | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.554); catalogued as COSV61667216; called by muse, mutect2, varscan2
- C7 | c.2375G>A p.R792Q | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.335); catalogued as rs372359270; called by muse, mutect2, varscan2
- C7orf25 | c.144C>A p.F48L | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV63273701; called by muse, mutect2, varscan2
- C7orf26 | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV60420334; called by muse, mutect2, varscan2
- C7orf31 | c.1740C>A p.F580L | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.137); catalogued as COSV99384146, COSV99384164; called by muse, mutect2
- C7orf31 | c.1387C>A p.H463N | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT tolerated (0.99); PolyPhen benign (0.023); catalogued as COSV52219915; called by muse, varscan2
9,080 further variants in this file (6,589 protein-altering or splice-affecting, 1,593 silent, 898 other) are not listed here.
